CCDI case PBCMUA — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Other and ill-defined sites within respiratory system and intrathoracic organs.
https://portal.gdc.cancer.gov/cases/a905ca67-fc8e-4d7b-bec1-8b1aea208618

Demographics
Sex at birth: female; Race: white.

Diagnoses (1)
1. Myofibroblastic tumor, NOS: ICD-O-3 morphology code: 8825/1; Tissue or organ of origin: Upper lobe, lung; Age at diagnosis: 9.4 years (3,446 days).

Biospecimens (3 samples)
- Sample 0DW72L: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DW72T: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DW745: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
